Gene-level copy-number profile of specimen HCM-BROD-0561-C43-85M from HCMI case HCM-BROD-0561-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 63.4 years (23,161 days).
Specimen HCM-BROD-0561-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b0e9bed8-8bba-499b-a90b-962ee37cd2f8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0561-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/e5ffa91f-beca-4d2f-9119-d4b4569c19b5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 569; copy number 2: 17,356; copy number 3: 20,637; copy number 4: 13,864; copy number 5: 4,200; copy number 6: 1,018; copy number 7: 883; copy number 8: 277; copy number 9: 59; copy number 11: 13.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,232 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:143,091,362–143,768,352, 1 gene, copy number 7 (within-gene range 3–7): ARHGAP15.
- chr2:143,099,936–143,100,612, 1 gene, copy number 7: MTATP6P5.
- chr2:143,162,078–146,478,113, 35 genes, copy number 7: AC013437.1, AC079793.1, AC092652.2, ARHGAP15-AS1, AC092652.1, AC079584.2, AC079584.1, Y_RNA, AC016910.1, GTDC1, ZEB2, AC009951.5, AC009951.4, ZEB2-AS1, AC009951.2, AC009951.1, AC009951.3, AC009951.6, LINC01412, TEX41, AC023128.1, AC023128.2, SGCEP1, LINC01966, AC096666.1, RPL6P5, AC092484.1, AC079163.2, AC079163.1, METAP2P1, AC079248.1, AC079248.2, RNU7-2P, RPL17P12, OTX2P2.
- chr6:485,154–10,222,161, 170 genes, copy number 7–8 (broad region; genes not listed).
- chr8:46,028,804–115,809,673, 1,002 genes, copy number 7–11 (broad region; genes not listed).
- chr22:38,424,288–38,794,143, 23 genes, copy number 7 (within-gene range 5–7): Z97056.1, KCNJ4, Z97056.3, KDELR3, DDX17, DMC1, RPS29P31, FAM227A, CBY1, AL021707.4, AL021707.2, AL021707.9, TOMM22, JOSD1, GTPBP1, PRDX3P1, AL021707.5, SUN2, AL021707.3, AL021707.8, AL021707.1, AL021707.6, AL021707.7.

Autosomal genes at a single copy (total copy number 1): 92. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
